Somatic mutation profile of tumor specimen MMRF_2659_1_BM_CD138pos (aliquot MMRF_2659_1_BM_CD138pos_T1_KHS5U_L13776) from MMRF case MMRF_2659, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,941 days).
Specimen MMRF_2659_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d69be60-6899-4cbd-9f74-be0bb34941ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2659_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2659_1_PB_WBC_C2_KHS5U_L13777; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ccdc5ba-3954-439c-b048-c700ce63e6de

The open-access MAF lists 266 somatic variants for this specimen: 97 protein-altering or splice-affecting, 48 silent, 121 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, 3'UTR 66, Silent 48, Intron 32, Nonsense Mutation 13, 5'UTR 10, 3'Flank 8, RNA 3, Splice Site 3, Splice Region 3, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033190, CM013721, CM023927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAPSN | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs104894294, CM064188, COSV54084600; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACSM2B | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as COSV100313274; called by muse, mutect2, varscan2
- ATM | c.8854C>G p.L2952V | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs1555151218, COSV53737833, COSV53759315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERG | c.2062T>G p.Y688D | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs1342714946; called by muse, varscan2
- CLEC4G | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.052); catalogued as rs1162589139; called by muse, mutect2, varscan2
- DAO | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV57322616; called by muse, mutect2, varscan2
- DEK | c.186A>C p.K62N | Missense Mutation (SNP) | VAF 162/404 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as rs1230514090; called by muse, mutect2, varscan2
- DMRTA1 | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV57924237; called by muse, mutect2, varscan2
- DNAJB6 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs760657136; called by muse, mutect2, varscan2
- DOCK4 | c.5277A>G p.K1759= | Splice Region (SNP) | VAF 77/178 reads (43%) | catalogued as rs1387796400; called by muse, mutect2, varscan2
- DUSP2 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99997057; called by muse, mutect2, varscan2
- ESCO1 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52521108; called by muse, mutect2, varscan2
- FAN1 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as rs1408556558, CM126655; called by muse, mutect2, varscan2
- FLI1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV55647873; called by muse, mutect2, varscan2
- GGN | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1293231861; called by muse, mutect2, varscan2
- H1-4 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV56803380; called by muse, mutect2, varscan2
- HECW2 | c.4355G>A p.G1452D | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027776486, COSV53664324; called by muse, mutect2, varscan2
- HTR1D | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs140806772; called by muse, mutect2, varscan2
- IGLV2-11 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.007); catalogued as rs567880120; called by muse, mutect2, varscan2
- MMP15 | c.910+4C>T | Splice Region (SNP) | VAF 34/72 reads (47%) | catalogued as rs376562195; called by muse, mutect2, varscan2
- MUC17 | c.11257A>G p.T3753A | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60288610; called by muse, mutect2, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs537060918; called by mutect2, varscan2
- MYH1 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs758144869; called by muse, mutect2, varscan2
- NAPB | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1261587337, COSV65464406, COSV65464744; called by muse, mutect2, varscan2
- NCKAP5 | c.1925C>A p.S642* | Nonsense Mutation (SNP) | VAF 32/197 reads (16%) | catalogued as COSV58476599; called by muse, mutect2, varscan2
- OAS2 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV60802341; called by muse, mutect2, varscan2
- OR4N2 | c.63A>C p.Q21H | Missense Mutation (SNP) | VAF 128/436 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100269961, COSV60053544; called by muse, mutect2, varscan2
- PARP9 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100831253; called by muse, mutect2, varscan2
- PTPN21 | c.1443C>A p.Y481* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV60853405; called by muse, mutect2, varscan2
- S100A10 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1487766517; called by muse, mutect2, varscan2
- SAMHD1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1482152853, COSV53429009; called by muse, mutect2, varscan2
- SDK1 | c.5489G>A p.G1830D | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745305864, COSV67369654; called by muse, mutect2, varscan2
- SLC17A3 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142438811; called by muse, mutect2, varscan2
- SLC4A8 | c.2975T>C p.M992T | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs376260949; called by muse, mutect2, varscan2
- SLC7A3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as rs776425784, COSV53227212; called by muse, mutect2, varscan2
- SPDYC | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs781661812, COSV101017118; called by muse, mutect2, varscan2
- ZBTB16 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs764450497; called by muse, mutect2, varscan2
- ZNF2 | c.1288C>T p.R430W (on ENST00000611147 / NM_001291605.2; = p.R417W on NM_021088.4) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1347185640; called by muse, mutect2, varscan2
- ACSM2A | c.243G>A p.W81* (on ENST00000219054; = p.W2* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 38/836 reads (5%) | called by muse, mutect2
- AFF1 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- AK7 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ANK2 | c.8066T>C p.V2689A | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATG9B | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ATM | c.968dup p.S324Kfs*6 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- BCL9L | c.3941T>A p.I1314N | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BTG2 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- C3orf20 | c.1529C>G p.A510G | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- C3orf38 | c.857T>C p.L286S | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1G | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CAPZA3 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2
- CBLB | c.1592A>T p.K531M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- CD28 | c.349A>C p.M117L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CILP2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CSPG5 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DNAH8 | c.3431A>C p.E1144A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- EHD1 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 172/475 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETS1 | c.1110+1G>A p.X370_splice | Splice Site (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- FLT1 | c.3738C>A p.S1246R | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FOXA1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.18424C>T p.Q6142* | Nonsense Mutation (SNP) | VAF 54/150 reads (36%) | called by muse, varscan2
- GABRB2 | c.1505T>A p.F502Y (on ENST00000274547; = p.F464Y on NM_000813.3) | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJE1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2
- GLMP | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA4 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GRIN3A | c.1611C>A p.C537* | Nonsense Mutation (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- GTPBP1 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HAUS1 | c.579A>T p.R193S | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- HUWE1 | c.5488G>A p.D1830N | Missense Mutation (SNP) | VAF 84/117 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- IARS2 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ICAM5 | c.2771C>T p.A924V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KCNK15 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KIAA1549L | c.456T>A p.H152Q (on ENST00000321505; = p.H449Q on NM_012194.3) | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MCM4 | c.1343T>C p.L448S | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MLPH | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MYBL1 | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2
- NRXN3 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 71/116 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- NUP210 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- OR1J1 | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OR2M5 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- OR9I1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PARD3 | c.3382G>T p.A1128S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDZRN3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEDS1 | c.124A>C p.K42Q | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PJA2 | c.802A>C p.K268Q | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PMPCB | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- PSD3 | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RAB6A | c.363_365del p.I121del | In Frame Del (DEL) | VAF 58/146 reads (40%) | called by pindel, varscan2
- RASA2 | c.684+2T>C p.X228_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1689-1G>T p.X563_splice | Splice Site (SNP) | VAF 114/318 reads (36%) | called by muse, mutect2, varscan2
- SLIT2 | c.2712dup p.F905Ifs*14 | Frame Shift Ins (INS) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- SRCAP | c.5417T>A p.L1806* | Nonsense Mutation (SNP) | VAF 70/181 reads (39%) | called by muse, mutect2, varscan2
- SUPT5H | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- THAP7 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMSB4X | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM41 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, varscan2
- ZNF300 | c.265+1_265+5dup | Splice Region (INS) | VAF 26/192 reads (14%) | called by mutect2, varscan2
- ACSM2B | c.333G>A p.V111= | Silent (SNP) | VAF 24/386 reads (6%) | catalogued as COSV100313042; called by muse, mutect2
- ADAMTS16 | c.66C>T p.A22= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- AHCTF1 | c.129G>A p.V43= (on ENST00000366508; = p.V17= on NM_015446.5) | Silent (SNP) | VAF 39/239 reads (16%) | called by muse, mutect2, varscan2
- AP1G2 | c.1569T>G p.T523= | Silent (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- BRINP1 | c.822G>A p.P274= | Silent (SNP) | VAF 140/333 reads (42%) | catalogued as rs373574674, COSV99777141; called by muse, mutect2, varscan2
- BUD13 | c.1293G>A p.V431= | Silent (SNP) | VAF 114/351 reads (32%) | called by muse, mutect2, varscan2
- C1orf116 | c.45C>G p.P15= | Silent (SNP) | VAF 81/249 reads (33%) | called by muse, mutect2, varscan2
- DNAH1 | c.966A>T p.T322= | Silent (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
- DSC1 | c.777T>G p.T259= | Silent (SNP) | VAF 101/240 reads (42%) | called by muse, mutect2, varscan2
- FAT4 | c.3927T>C p.N1309= | Silent (SNP) | VAF 6/139 reads (4%) | called by muse, mutect2
- FBXL7 | c.1383C>T p.V461= | Silent (SNP) | VAF 31/101 reads (31%) | called by muse, varscan2
- FLT1 | c.996A>G p.A332= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs945408770; called by muse, mutect2, varscan2
- FOXJ1 | c.1086G>A p.S362= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs767689240; called by muse, mutect2, varscan2
- GABRB2 | c.1506C>T p.F502= (on ENST00000274547; = p.F464= on NM_000813.3) | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as COSV50953623, COSV99195865; called by muse, mutect2, varscan2
- H2BC7 | c.372C>T p.S124= | Silent (SNP) | VAF 124/369 reads (34%) | catalogued as rs766252240; called by muse, mutect2, varscan2
- HR | c.2403C>T p.I801= | Silent (SNP) | VAF 93/310 reads (30%) | catalogued as rs747781351; called by muse, mutect2, varscan2
- IARS2 | c.1929G>A p.R643= | Silent (SNP) | VAF 34/315 reads (11%) | catalogued as COSV56962658; called by muse, mutect2, varscan2
- IRGQ | c.219G>A p.A73= | Silent (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- ITGA3 | c.2079C>G p.A693= | Silent (SNP) | VAF 176/521 reads (34%) | called by muse, mutect2, varscan2
- KCNK12 | c.327G>A p.A109= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.264A>T p.P88= | Silent (SNP) | VAF 105/268 reads (39%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1869C>A p.A623= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- MAP4 | c.2271C>T p.A757= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs760286280; called by muse, varscan2
- MLF2 | c.625C>T p.L209= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs752181816; called by muse, mutect2, varscan2
- MRTFB | c.828G>A p.V276= | Silent (SNP) | VAF 296/468 reads (63%) | catalogued as rs561963232; called by muse, mutect2, varscan2
- MUC16 | c.41772G>A p.E13924= | Silent (SNP) | VAF 33/55 reads (60%) | called by muse, mutect2, varscan2
- MUC16 | c.40699C>T p.L13567= | Silent (SNP) | VAF 69/181 reads (38%) | called by muse, mutect2, varscan2
- MVK | c.57A>G p.E19= | Silent (SNP) | VAF 72/226 reads (32%) | catalogued as COSV57170059; called by muse, mutect2, varscan2
- NEURL1B | c.1233C>T p.T411= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- NR2E3 | c.768G>A p.A256= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs1448837236; ClinVar: likely benign; called by muse, mutect2
- OLFM1 | c.123G>T p.L41= | Silent (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- OR52E4 | c.636G>A p.V212= | Silent (SNP) | VAF 117/276 reads (42%) | catalogued as rs145588560, COSV57624296; called by muse, mutect2, varscan2
- PAPPA | c.2535C>T p.D845= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs377702306, COSV60288215; called by muse, mutect2, varscan2
- PFKFB3 | c.751C>T p.L251= | Silent (SNP) | VAF 27/293 reads (9%) | called by muse, mutect2
- PPP1R18 | c.543C>T p.D181= | Silent (SNP) | VAF 145/388 reads (37%) | called by muse, mutect2, varscan2
- PPP1R26 | c.3198C>T p.P1066= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs774074084, COSV63357127; called by muse, mutect2, varscan2
- PUM1 | c.729G>A p.R243= | Silent (SNP) | VAF 120/187 reads (64%) | called by muse, mutect2, varscan2
- SALL1 | c.3738G>A p.A1246= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs145953478; called by muse, mutect2, varscan2
- SCN3A | c.909G>A p.G303= | Silent (SNP) | VAF 75/257 reads (29%) | called by muse, mutect2, varscan2
- SEMA3D | c.723A>G p.A241= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- SLC43A1 | c.111G>A p.L37= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SNAP23 | c.513G>A p.L171= | Silent (SNP) | VAF 20/334 reads (6%) | catalogued as COSV51041561; called by muse, mutect2
- STPG2 | c.507G>A p.K169= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54795354; called by muse, mutect2
- TPBG | c.657C>T p.S219= | Silent (SNP) | VAF 85/196 reads (43%) | catalogued as rs1221945706; called by muse, mutect2, varscan2
- TTN | c.80364A>G p.V26788= (on ENST00000591111; = p.V19364= on NM_003319.4) | Silent (SNP) | VAF 76/209 reads (36%) | called by muse, mutect2, varscan2
- ULK2 | c.1299T>C p.S433= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- URB1 | c.2556C>G p.L852= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs1284689729; called by muse, mutect2, varscan2
- ACRP1 | n.20A>C | RNA (SNP) | VAF 87/220 reads (40%) | called by muse, mutect2, varscan2
- AMPH | c.*387T>C | 3'UTR (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*3081T>C | 3'UTR (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- ASTN1 | c.*2423C>T | 3'UTR (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- ASXL1 | c.-262C>A | 5'UTR (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021253 T>A | 5'Flank (SNP) | VAF 66/183 reads (36%) | called by muse, mutect2, varscan2
- BDNF | c.*255C>T | 3'UTR (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.*1740C>T | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- C2CD5 | c.-29-57C>T | Intron (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- C8orf31 | n.634C>T | RNA (SNP) | VAF 53/132 reads (40%) | catalogued as rs371078298; called by muse, mutect2, varscan2
- C9orf72 | c.*161A>G | 3'UTR (SNP) | VAF 51/133 reads (38%) | called by muse, varscan2
- CATSPERG | c.2094+47A>G | Intron (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- CCNG2 | c.911+411C>G | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- CCR2 | c.942-412G>A | Intron (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
- CD163L1 | c.124+1932C>T | Intron (SNP) | VAF 28/100 reads (28%) | catalogued as COSV58017378; called by muse, mutect2, varscan2
- CD276 | c.*791G>T | 3'UTR (SNP) | VAF 216/431 reads (50%) | called by muse, mutect2, varscan2
- CD84 | chr1:160546369 T>C | 3'Flank (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- CDC42BPA | c.4909+926_4909+927insCA | Intron (INS) | VAF 14/49 reads (29%) | called by pindel, varscan2
- CDK12 | c.-217A>G | 5'UTR (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- CDKN1B | c.-344A>T | 5'UTR (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- CDON | c.*3700C>T | 3'UTR (SNP) | VAF 116/329 reads (35%) | catalogued as COSV54997266; called by muse, mutect2, varscan2
- CEP290 | c.6012-44dup | Intron (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- CHP2 | c.*1282C>G | 3'UTR (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2301C>T | Intron (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- CPLX4 | c.*900del | 3'UTR (DEL) | VAF 20/48 reads (42%) | catalogued as rs959471921; called by mutect2, varscan2
- CPT1C | c.1731+36T>A | Intron (SNP) | VAF 108/292 reads (37%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.-231dup | 5'UTR (INS) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- CTBP2 | c.58+12713G>A | Intron (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- CUBN | c.*895G>A | 3'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- DIPK1B | chr9:136726200 G>A | 3'Flank (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- DMWD | c.-11G>C | 5'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- DPP10 | c.*1786C>A | 3'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.*148C>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- EFCAB2 | c.*2424C>T | 3'UTR (SNP) | VAF 41/148 reads (28%) | called by muse, mutect2, varscan2
- ERAP2 | c.*1110G>A | 3'UTR (SNP) | VAF 40/66 reads (61%) | called by muse, mutect2, varscan2
- EZR | c.*709_*711del | 3'UTR (DEL) | VAF 13/25 reads (52%) | catalogued as rs951168007; called by mutect2, pindel, varscan2
- FAM98A | c.*1108T>C | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- FCMR | c.373+102A>G | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- FMN1 | c.1867+2704G>T | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- FNIP1 | c.*1375A>C | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- FOXK1 | c.*5117G>A | 3'UTR (SNP) | VAF 31/92 reads (34%) | catalogued as rs1377696880; called by muse, mutect2, varscan2
- FSD1L | c.*4545A>C | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- GCSAM | c.*2545A>G | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, varscan2
- GCSAM | c.*2518G>C | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, varscan2
- GK5 | c.*234G>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- GLI4 | c.224-23G>A | Intron (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1559C>A | 3'UTR (SNP) | VAF 60/172 reads (35%) | catalogued as rs1008492226; called by muse, varscan2
- GPAT4 | c.*1592C>T | 3'UTR (SNP) | VAF 54/164 reads (33%) | called by muse, varscan2
- HBE1 | c.-267+36849G>T | Intron (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- HGF | c.*3268dup | 3'UTR (INS) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- HIGD1A | c.-23+135G>A | Intron (SNP) | VAF 87/268 reads (32%) | called by muse, mutect2, varscan2
- HK2 | c.*311C>T | 3'UTR (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- IARS2 | c.1946+133G>A | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- IFIH1 | c.-247C>T | 5'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899550 A>G | 3'Flank (SNP) | VAF 97/146 reads (66%) | called by muse, mutect2, varscan2
- IKBKE | c.1836-34G>T | Intron (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- INPP4A | c.*626T>A | 3'UTR (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- KIF1A | c.4589+86G>A | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- KLHL12 | c.*588C>T | 3'UTR (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- LDOC1 | c.-53G>A | 5'UTR (SNP) | VAF 28/44 reads (64%) | catalogued as COSV65159573; called by muse, mutect2, varscan2
- LINC02869 | n.274G>A | RNA (SNP) | VAF 17/374 reads (5%) | called by muse, mutect2
- LMBRD2 | c.*1230A>G | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- LPP | c.*5464G>A | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2
- LRATD1 | c.*136C>A | 3'UTR (SNP) | VAF 53/144 reads (37%) | called by muse, mutect2, varscan2
- MBD5 | c.*3242_*3243del | 3'UTR (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- MBOAT2 | c.*682G>A | 3'UTR (SNP) | VAF 55/130 reads (42%) | catalogued as rs1339976725; called by muse, mutect2, varscan2
- MED6 | c.183-30G>A | Intron (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- MMAB | c.*1150C>T | 3'UTR (SNP) | VAF 57/160 reads (36%) | catalogued as rs1023371210; called by muse, mutect2, varscan2
- MOBP | chr3:39515890 T>C | 3'Flank (SNP) | VAF 66/190 reads (35%) | called by muse, mutect2, varscan2
- MS4A8 | c.535-3003dup | Intron (INS) | VAF 56/138 reads (41%) | catalogued as rs775266592; called by mutect2, varscan2
- MTCL1 | chr18:8832272 A>G | 3'Flank (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2
- NCOA1 | c.*1185dup | 3'UTR (INS) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- NRG1 | c.700+964G>T | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- NUDT12 | c.*296C>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- P4HA2 | chr5:132192156 A>G | 3'Flank (SNP) | VAF 34/67 reads (51%) | catalogued as rs1006460524; called by muse, mutect2, varscan2
- PCDH10 | c.*1036T>A | 3'UTR (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
- PCSK9 | c.-251C>T | 5'UTR (SNP) | VAF 69/137 reads (50%) | catalogued as COSV100135082; called by muse, mutect2, varscan2
- PDE4DIP | c.637-8280G>A | Intron (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- PDGFB | c.-218C>T | 5'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- PFKFB3 | c.*464C>T | 3'UTR (SNP) | VAF 61/250 reads (24%) | called by muse, mutect2, varscan2
- PGGT1B | c.*841G>A | 3'UTR (SNP) | VAF 43/80 reads (54%) | catalogued as rs1243627523; called by muse, mutect2, varscan2
- PIK3IP1 | c.*1373C>T | 3'UTR (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- PIM1 | c.*435_*438del | 3'UTR (DEL) | VAF 59/169 reads (35%) | catalogued as rs1225617864; called by mutect2, pindel, varscan2
- PLXNA2 | c.*1790A>G | 3'UTR (SNP) | VAF 188/284 reads (66%) | called by muse, mutect2, varscan2
- PREX1 | c.3775+30C>A | Intron (SNP) | VAF 136/365 reads (37%) | called by muse, mutect2, varscan2
- PTPRB | chr12:70517802 C>T | 3'Flank (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- PXMP2 | c.*211C>T | 3'UTR (SNP) | VAF 109/401 reads (27%) | catalogued as rs897105679; called by muse, mutect2, varscan2
- RAB30 | c.*7930T>G | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- RAP2B | c.*3095A>C | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- RASSF3 | c.*77G>A | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- RIPOR2 | c.*1218A>T | 3'UTR (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- SCARF1 | c.1010+42C>G | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- SGCZ | c.-475G>C | 5'UTR (SNP) | VAF 33/105 reads (31%) | catalogued as rs750880128; called by muse, mutect2, varscan2
- SIRPB1 | c.76+15049G>A | Intron (SNP) | VAF 73/117 reads (62%) | called by muse, mutect2, varscan2
- SLC13A3 | c.*1130T>A | 3'UTR (SNP) | VAF 86/235 reads (37%) | called by muse, mutect2, varscan2
- SLC2A4 | c.*318G>C | 3'UTR (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*27G>A | 3'UTR (SNP) | VAF 112/291 reads (38%) | catalogued as rs750945665, COSV99134281; called by muse, mutect2, varscan2
- SMC1A | c.*5394A>G | 3'UTR (SNP) | VAF 13/101 reads (13%) | catalogued as rs1026596338; called by muse, mutect2, varscan2
- SOAT1 | c.*3599G>C | 3'UTR (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- SOX10 | chr22:37970750 G>C | 3'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- SPICE1 | c.*1334T>C | 3'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- STAU2 | c.1530+938_1530+939del | Intron (DEL) | VAF 89/312 reads (29%) | catalogued as rs976488923; called by pindel, varscan2
- STMN3 | c.*1272C>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as rs1334123541; called by muse, mutect2, varscan2
- STX18 | c.430+31A>G | Intron (SNP) | VAF 34/52 reads (65%) | called by muse, mutect2, varscan2
- TBX2 | c.1052-51C>T | Intron (SNP) | VAF 83/212 reads (39%) | catalogued as rs1258000235; called by muse, mutect2, varscan2
- THNSL1 | c.*392T>G | 3'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- TIFA | c.*528A>C | 3'UTR (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- TMEM255B | c.423+140G>A | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as rs374031069; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975584 G>A | 5'Flank (SNP) | VAF 136/177 reads (77%) | catalogued as rs781125291; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.173-26C>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- TNFSF18 | c.*842A>C | 3'UTR (SNP) | VAF 152/215 reads (71%) | called by muse, mutect2, varscan2
- TNRC6B | c.*2818A>C | 3'UTR (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- TNRC6B | c.*2934A>T | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- UROS | c.661-473C>G | Intron (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- VGLL2 | c.*729T>A | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- VGLL2 | c.*730A>T | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC11B | c.784+178A>T | Intron (SNP) | VAF 30/315 reads (10%) | called by muse, mutect2
- ZDHHC6 | c.*401G>A | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- ZNF286A | c.*691T>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- ZNF420 | c.*459C>T | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- ZNF776 | c.*3297G>A | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
